Somatic mutation profile of tumor specimen C3L-03624-02 (aliquot CPT0198600025) from CPTAC case C3L-03624, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.6 years (25,430 days).
Specimen C3L-03624-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f978e2be-b520-4105-b17f-a7371b0196d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03624-31 (Blood Derived Normal), aliquot CPT0198630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5108ef8c-b072-4499-80e0-32ee1010d71e

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 5, Nonsense Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 33/563 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SMAD4 | c.1091T>G p.L364W | Missense Mutation (SNP) | VAF 37/560 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377767350, CM064284, COSV61684370, COSV61687936; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 44/678 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- BTK | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs368549990, COSV58117893, COSV58121329; called by muse, mutect2
- CNOT1 | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 18/636 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV55315668; called by muse, mutect2
- COL6A3 | c.4726C>T p.R1576W | Missense Mutation (SNP) | VAF 32/668 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs773979979; ClinVar: uncertain significance; called by muse, mutect2
- DCDC2C | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 33/662 reads (5%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); catalogued as COSV70978149; called by muse, mutect2
- ITPKB | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 42/736 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1373422478; called by muse, mutect2
- KCNT1 | c.1172C>T p.T391M (on ENST00000488444; = p.T410M on NM_020822.3) | Missense Mutation (SNP) | VAF 42/700 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as rs954342612, COSV53708640; called by muse, mutect2
- MAPK3 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 22/710 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321995174, COSV53777512; called by muse, mutect2
- NPIPB11 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 232/296 reads (78%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.876); catalogued as rs796341971; called by muse, varscan2
- PDHA2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 43/819 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs372154327; called by muse, mutect2
- PRICKLE2 | c.1064C>T p.P355L (on ENST00000295902; = p.P299L on NM_198859.4) | Missense Mutation (SNP) | VAF 28/921 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342755436; called by muse, mutect2
- PRR12 | c.1697C>T p.S566F (on ENST00000615927; = p.S1387F on NM_020719.3) | Missense Mutation (SNP) | VAF 52/870 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773731923; called by muse, mutect2
- SCML4 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 42/1083 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164896830; called by muse, mutect2
- SMCO3 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 36/776 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs780721771; called by muse, mutect2
- SPTBN4 | c.5837G>A p.R1946H | Missense Mutation (SNP) | VAF 46/862 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs370454922, COSV100150961; called by muse, mutect2
- CACNG4 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 40/820 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- DLL3 | c.1034T>A p.F345Y | Missense Mutation (SNP) | VAF 55/680 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.095); called by muse, mutect2
- DLX2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 50/1074 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); called by muse, mutect2
- EXO5 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.021); called by muse, mutect2
- FAM228B | c.885T>G p.Y295* | Nonsense Mutation (SNP) | VAF 22/400 reads (6%) | called by muse, mutect2
- KALRN | c.1956G>A p.E652= | Splice Region (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- MARK2 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 37/801 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MFHAS1 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by mutect2, varscan2
- NPAS4 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 27/826 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- PDIA3 | c.92C>A p.T31K | Missense Mutation (SNP) | VAF 36/864 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2
- PITPNM2 | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 68/912 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA3A | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- SLC10A7 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.03); called by muse, mutect2
- TMED4 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 38/570 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- CPED1 | c.72G>A p.V24= | Silent (SNP) | VAF 36/653 reads (6%) | called by muse, mutect2
- EPB41L3 | c.1878G>T p.P626= | Silent (SNP) | VAF 67/896 reads (7%) | called by muse, mutect2
- FAM135B | c.2223C>T p.S741= | Silent (SNP) | VAF 108/728 reads (15%) | catalogued as rs375012240, COSV52723444; called by muse, mutect2, varscan2
- KTN1 | c.1215G>A p.Q405= | Silent (SNP) | VAF 10/300 reads (3%) | called by muse, mutect2
- USP2 | c.1770C>T p.D590= | Silent (SNP) | VAF 59/854 reads (7%) | catalogued as rs910013381; called by muse, mutect2
- KCTD18 | c.661+42T>A | Intron (SNP) | VAF 8/188 reads (4%) | catalogued as COSV63344084; called by muse, mutect2
